Somatic mutation profile of tumor specimen TCGA-ET-A3BU-01A (aliquot TCGA-ET-A3BU-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BU, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.8 years (10,510 days).
Specimen TCGA-ET-A3BU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 512f8490-d109-4ee4-bd40-cf4d94b813fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BU-10A (Blood Derived Normal), aliquot TCGA-ET-A3BU-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f369aa0-fddf-4a8a-b99c-8942d562d672

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IPO11 | c.2132A>G p.N711S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs768110774, COSV57575245; called by muse, mutect2, varscan2
- PPRC1 | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53384625; called by muse, mutect2, varscan2
- GIT1 | c.237C>T p.S79= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV56608649; called by muse, mutect2, varscan2
- SHLD2 | c.2110T>C p.L704= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100079464; called by muse, mutect2, varscan2
- C9orf106 | n.583G>T | RNA (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
